Gene-level copy-number profile of tumor specimen TCGA-25-1323-01A from TCGA case TCGA-25-1323, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-25-1323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0255205f-8e52-4d29-aa0a-7eecf30fc836.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,472 have no estimate.
https://portal.gdc.cancer.gov/files/5f40db56-c6ff-4fb6-baad-361dfc9772f9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,406; copy number 2: 16,118; copy number 3: 16,575; copy number 4: 13,992; copy number 5: 3,273; copy number 6: 1,708; copy number 7: 2,079.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-1323-01A-01D-0452-01): tumor purity 0.73, ploidy 3.32, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,079 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,544,205–197,888,436, 1,463 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:19,918,981–20,415,754, 10 genes, copy number 7 (within-gene range 4–7): AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:129,611,720–129,785,185, 7 genes, copy number 7: NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1.
- chr7:131,661,952–131,702,653, 3 genes, copy number 7: EEF1B2P6, AC093106.1, AC093106.2.
- chr10:77,730,766–78,178,186, 15 genes, copy number 7: AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1.
- chr13:44,094,822–44,405,984, 10 genes, copy number 7 (within-gene range 6–7): LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8.
- chr13:44,432,144–44,432,678, 1 gene, copy number 7: AL138960.2.
- chr14:67,819,779–68,730,218, 9 genes, copy number 7 (within-gene range 4–7): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2.
- chr19:10,871,553–17,310,236, 373 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:28,294,093–28,386,204, 2 genes, copy number 7: AC020905.1, AC005580.1.
- chr19:29,526,499–30,016,612, 12 genes, copy number 7 (within-gene range 6–7): VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr20:472,498–5,611,006, 159 genes, copy number 7 (broad region; genes not listed).
- chr21:42,599,280–43,107,570, 15 genes, copy number 7: LINC01671, AP001626.1, PDE9A, PDE9A-AS1, LINC01668, AP001628.2, AP001628.1, WDR4, NDUFV3, ERVH48-1, MIR5692B, AP001630.1, PKNOX1, CBS, U2AF1.

Autosomal genes at a single copy (total copy number 1): 1,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
